Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GO, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GO-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Excision recurrent melanoma left lower leg. Specimen tissue from 6 o'clock deep margin. ? presence of malignancy. Hx previous wide excision of melanoma left lower leg 5yrs ago and skin graft - see .
Has recent SCC excised from skin graft site L lower leg. Now P/W recurrent melanoma
L lower leg on FNAB. Specimen E/O recurrent melanoma L lower leg.

FROZEN SECTION REPORT

SPECIMEN: 1. Calf ? melanoma left posterior 6 o'clock deep margin.
REPORT: 1. **Fibrous tissue. No evidence of malignancy is seen.**
PHONED TO: Dr
DATE: TIME: REPORTED BY:
SECTIONED BY:

1CD-0-3
Melanoma, amelanotic
8730/3
Site: subcutaneous tissue,
calf C49.2
lw 4/10/11

MACROSCOPIC DESCRIPTION

(Dr
Two specimens were received.

1. "CALF ? MELANOMA LEFT POSTERIOR 6 O'CLOCK DEEP MARGIN". A small piece of none oriented cauterised fatty tissue 7 x 2 x 2mm. All embedded for frozen section ion block A.
2. "MELANOMA RECURRENT LEFT LEG MARKING STITCH SUPERIOR". An oval shaped piece of skin 45 x 40 x 25mm deep, with a dermal - subcutaneous light brown nodule 15 x 15 x 20mm. A superior marking suture is present, designated 12 o'clock. 3 o'clock half blue, 9 o'clock half black.
A - B, C - D. Two full face transverse sections.
A small portion of the tumour was taken for tumour banking at a fresh stage - (Dr

MICROSCOPIC REPORT

1. "Calf ? melanoma left posterior 6 o'clock deep margin":
Dense fibrous tissue and adipose tissue. No evidence of malignancy seen.
2. "Melanoma recurrent left leg marking stitch superior":
The sections show an undifferentiated non-pigmented epithelioid neoplasm involving the subcutis and adjacent dermis. It is 0.1mm from the deep inked margin of excision (2B) and <0.1mm from the nearest (blue ink 0 3 o'clock) lateral margin.

SUMMARY

Skin left posterior calf - recurrent amelanotic melanoma, close to margins.

REPORTED BY:

No evidence TCGA sample taken		
Case is (curie):		

lw 4/23/11

Source: NCI Genomic Data Commons file 52b7ee29-8436-4bb4-ac68-2f18cb9884e9 (TCGA-EE-A2GO.FCD0B833-0944-43BE-837F-8E2F38E937DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).